Somatic mutation profile of tumor specimen RC-B6SN-TTP1-A (aliquot RC-B6SN-TTP1-A-1-1-D-A94K-47) from RC case RC-B6SN, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph nodes of multiple regions; Age at diagnosis: 69.0 years (25,202 days).
Specimen RC-B6SN-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db92e138-2dab-4240-a4dd-eacb0f97763e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6SN-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6SN-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/726ffc7a-80b6-481b-9cb1-87b1979c9ee3

The open-access MAF lists 17 somatic variants for this specimen: 7 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 6, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.516G>C p.R172S | Missense Mutation (SNP) | VAF 15/207 reads (7%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1057519736, COSV57468772, COSV57468910, COSV57481094; ClinVar: pathogenic; called by muse, mutect2
- DNAI1 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs921726236; called by muse, mutect2
- EPPK1 | c.7897G>A p.A2633T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.691); catalogued as rs1432999819; called by mutect2, varscan2
- SIGLEC1 | c.3770G>A p.R1257Q | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs753235912, COSV104390141; called by muse, mutect2
- TET2 | c.4642C>T p.Q1548* | Nonsense Mutation (SNP) | VAF 24/174 reads (14%) | catalogued as COSV54401466; called by muse, mutect2, varscan2
- TIAM2 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1020604692; called by muse, mutect2
- RAG1 | c.2861G>C p.G954A | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CST5 | c.69C>T p.A23= | Silent (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2
- EPPK1 | c.9696G>C p.T3232= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as rs1196498665; called by muse, mutect2
- KIAA1210 | c.3624C>T p.S1208= | Silent (SNP) | VAF 30/293 reads (10%) | called by muse, mutect2
- LRRFIP1 | c.1647C>T p.I549= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- MUC5AC | c.5883T>C p.I1961= | Silent (SNP) | VAF 16/175 reads (9%) | catalogued as rs1461033952; called by muse, mutect2
- SERPIND1 | c.99A>G p.E33= | Silent (SNP) | VAF 21/210 reads (10%) | catalogued as rs143785358; called by muse, mutect2
- TYR | c.279C>A p.G93= | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- ZXDA | c.816G>T p.A272= | Silent (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- DPF3 | c.32+1739G>T | Intron (SNP) | VAF 19/177 reads (11%) | called by muse, mutect2, varscan2
- LINC01165 | n.680A>G | RNA (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
